Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8WW, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8WW-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/23/28/14

FINAL PATHOLOGIC DIAGNOSIS

- A. Soft tissue, left anterior bladder neck, biopsy: Fibromuscular tissue, no tumor, no prostatic epithelium.
- B. Soft tissue, left posterior bladder neck, biopsy: Fibromuscular tissue, no tumor, no prostatic epithelium.
- C. Soft tissue, posterior midline, biopsy: Fibromuscular tissue with small focus of cauterized epithelioid cells; see comment.
- D. Soft tissue, left base, biopsy: Fibroadipose tissue, no tumor, no prostatic epithelium.
- E. Soft tissue, left posterior midline, biopsy: Fibroadipose tissue, no tumor, no prostatic epithelium.
- F. Lymph nodes, right pelvic, dissection: No tumor in eleven lymph nodes (0/11).
- G. Lymph nodes, left pelvic, dissection: Metastatic adenocarcinoma in one lymph node (1/9).**
- H. Prostate and seminal vesicles, radical prostatectomy: Prostatic adenocarcinoma, Gleason score 4+5=9, with bilateral seminal vesicle invasion; see comment.**

COMMENT:

Synoptic Comment for Prostate Tumors

[page 2 of 4]
- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left posterior apex, slides H2, H9; left posterior mid gland, slide H10; left posterior base, slides H11, H16, H18; left anterior apex, slides H2, H12; left anterior mid gland, slide H13; left anterior base, slides H14, H16; right posterior apex, slides H1, H6; right posterior mid gland, slide H7; right posterior base, slides H8, H17.
- **Estimated volume of tumor:** 7.7 cc.
- **Gleason score:** 4+5; primary pattern 4, secondary pattern 5.
- **Estimated volume > Gleason pattern 3:** 80%.
- **Involvement of capsule:** Tumor invades capsule (right posterior base, slide H8; left posterior apex, slide H9; left posterior mid gland, slide H10; left anterior base, slide H14; left posterior base, slide H18).
- **Extraprostatic extension:** Present, extensive (slides H9-H10, H14, H18).
- **Margin status for tumor:** Tumor cells are present <0.1 cm away from the margin. No definite tumor cells are identified at the inked margin.
However, rare cauterized glands (<0.1 cm in maximum dimension) that are too distorted by cautery to better classify are present at the left posterior base (slide H18).
Finally, on frozen section FS3 "posterior midline," there is a small focus of cauterized epithelioid cells which most likely represent plump endothelial cells of a small capillary but due to distortion, this possibility of this representing a small focus of prostatic adenocarcinoma cannot be completely excluded. This focus of cells is no longer present on permanent sections.
- **Margin status for benign prostatic glands:** No benign glands present at inked excision margins.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present; focally.
- **Tumor involvement of seminal vesicle:** Present; bilateral.
- **Perineural infiltration:** Present.
- **Lymphovascular invasion:** Present.
- **Lymph node status:** Positive;
- Total number of positive nodes: 1.
- Total number of nodes examined: 20.
- Size of largest metastasis in node: 0.3 cm
- Extranodal extension: None.
- **AJCC/UICC stage:** pT3bN1.

Specimen(s) Received

A: Left anterior bladder neck (FS)
B: Left posterior bladder neck (FS)
C: Posterior midline (FS)
D: Left base (FS)
E: Left posterior midline (FS)
F: Right pelvic lymph nodes
G: Left pelvic lymph nodes
H: Prostate + seminal vesicles (fresh)

Intraoperative Diagnosis

FS1 (A) Left anterior bladder neck, biopsy: Benign skeletal muscle, no prostatic glands.

FS2 (B) Left posterior bladder neck, biopsy: Benign skeletal muscle, no prostatic glands.

FS3 (C) Posterior midline, biopsy: Fibromuscular tissue with small focus of cauterized cells, cannot exclude benign prostate or carcinoma vs. endothelium. Dr. _____ concurs.

FS4 (D) Left base, biopsy: Benign muscular adipose tissue, no prostatic glands.

[page 3 of 4]
FS5 (F) Left posterior midline, biopsy: Benign neurovascular tissue, no prostatic glands.

Clinical History

The patient is a 65-year-old man. Review of the electronic medical record reveals the patient underwent needle core biopsies of the prostate for an abnormal DRE with a diagnosis of prostatic adenocarcinoma, Gleason grade 3+4/4+5, with perineural invasion. The patient now undergoes a robot-assisted radical prostatectomy with pelvic lymph node dissection.

Gross Description

The specimen is received in eight parts, each labeled with the patient's name and medical record number. Parts A-E and Part H are received fresh. Parts F and G are received in formalin.

Part A, additionally labeled "left anterior bladder neck - frozen," consists of red-tan cauterized, unoriented soft tissue (0.3 x 0.3 x 0.3 cm). The entire specimen is frozen for frozen section diagnosis 1, and subsequently submitted in cassette A1.

Part B, additionally labeled "left posterior bladder neck," consists of red-tan, cauterized, unoriented soft tissue (4 x 3 x 2 cm). The entire specimen is frozen for frozen section diagnosis 2, and subsequently submitted in cassette B1.

Part C, additionally labeled "posterior midline - FS," consists of pink-red unoriented soft tissue (0.3 x 0.1 x 0.1 cm). The entire specimen is frozen for frozen section diagnosis 3, and subsequently submitted in cassette C1.

Part D, additionally labeled "left base - FS," consists of white-tan unoriented irregular soft tissue (0.3 x 0.2 x 0.1 cm). The entire specimen is frozen for frozen section diagnosis 4, and subsequently submitted in cassette D1.

Part E, additionally labeled "left posterior midline - FS," consists of red-tan, unoriented, ovoid soft tissue fragments (0.4 x 0.3 x 0.2 cm in aggregate). The entire specimen is frozen for frozen section diagnosis 5, and subsequently submitted in cassette E1.

Part F, additionally labeled "right pelvic lymph nodes," consists of multiple small, soft, irregular to firm, unoriented, yellow-tan, fibrofatty tissue fragments (4.5 x 2 x 1 cm in aggregate). Multiple ovoid to irregular, firm, yellow-tan lymph node candidates (0.2-4.5 cm) are identified. The entire specimen is submitted as follows:

F1-F2:	One lymph node candidate, sectioned.	→
F3:	Three lymph node candidates, intact.	
F4:	Two lymph node candidates, intact.	
F5:	Two lymph node candidates, intact.	
F6:	Fibrofatty remnant.	

Part G, additionally labeled "left pelvic lymph nodes," consists of multiple soft to firm, irregular, unoriented, yellow-tan, fibrofatty tissue fragments (6.5 x 2.5 x 1.3 cm in aggregate). Multiple firm, irregular, yellow-tan lymph node candidates (0.3-6.0 cm) are identified. The entire specimen is submitted as follows:

G1-G3:	One lymph node candidate, sectioned.
G4:	One lymph node candidate, bisected.
G5:	One lymph node candidate, bisected.
G6:	One lymph node candidate, bisected.
G7:	Four lymph node candidates, intact.
G8:	Fibrofatty remnant.

Part H, additionally labeled "prostate and seminal vesicles," consists of an intact, red-tan radical prostatectomy specimen (43.5 gm; 3.5 cm from apex to base x 4.5 cm in width x 4 cm from anterior to

[page 4 of 4]
posterior) with attached seminal vesicle/vas deferens bundles (right 3.5 x 1.5 x 0.5 cm; left 4 x 1.5 x 0.5 cm).

GROSS PATHOLOGIC FINDINGS: There is a large, solid to diffuse, firm, white-tan tumor (2 x 2 x 1.5 cm) running along the left posterolateral apex through base (slices 2-9) with tumor appearing to extend beyond the capsule into the surrounding fibrofatty tissues and to the surgical margin in slices 5-9. No other nodules are identified. The tumor also appears to abut and focally extend into the left seminal vesicle. No other nodules are grossly identified. The anterior fibrous stroma is opened and the remaining capsule appears otherwise intact.

ORIENTED BY: Anatomic landmarks.

INKING:

- Right anterior: Green.
- Left anterior: Blue.
- Posterior: Black.

POTENTIAL STUDIES: Tissue is snap frozen for research purposes.

TOTAL NUMBER OF SLICES: 9 (inclusive of apical margin).

AVERAGE SLICE THICKNESS: 0.38 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

H1: Right apex.

H2: Left apex.

Right anterior quadrant

H3: Slice 3.

H4: Slice 6.

H5: Slice 8.

Right posterior quadrant

H6: Slice 3.

H7: Slice 6.

H8: Slice 8.

Left posterior quadrant

H9: Slice 3.

H10: Slice 6.

H11: Slice 8.

Left anterior quadrant

H12: Slice 3.

H13: Slice 6.

H14: Slice 8.

Bladder margins, entirely submitted in perpendicular sections

H15: Right.

H16: Left.

Prostatic/seminal vesicle junction and cross-section of vas deferens

H17: Right.

H18: Left.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Pathology Resident

Electronically signed out on

Pathologist

Source: NCI Genomic Data Commons file 40c146c9-9b37-446d-a07e-46d4b3296242 (TCGA-V1-A8WW.36FBC30B-6566-4C5F-BE51-D267B4F856B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).